Gene-level copy-number profile of tumor specimen TCGA-61-1730-01A from TCGA case TCGA-61-1730, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 78.1 years (28,508 days).
Specimen TCGA-61-1730-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.234848ba-4be8-4507-8ec0-462398e50a26.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1730-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4390cea0-30bd-4a1d-941f-003214999ac3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 888; copy number 2: 14,080; copy number 3: 17,181; copy number 4: 17,180; copy number 5: 6,566; copy number 6: 1,216; copy number 7: 1,061; copy number 8: 698; copy number 9: 90; copy number 15: 369; copy number 18: 413; copy number 19: 77.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1730-01A-01D-0577-01): tumor purity 0.8, ploidy 3.41, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,688 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:163,769,339–164,899,296, 10 genes, copy number 7 (within-gene range 5–7): AL355862.1, U3, NMNAT1P2, RNU5F-6P, HMGB3P6, PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1.
- chr1:246,682,108–248,919,946, 121 genes, copy number 7 (broad region; genes not listed).
- chr2:160,849,313–212,538,841, 799 genes, copy number 7 (broad region; genes not listed).
- chr9:123,109,500–123,268,586, 1 gene, copy number 9 (within-gene range 5–9): STRBP.
- chr9:123,356,170–125,257,071, 40 genes, copy number 9: CRB2, DENND1A, MIR601, MIR7150, AL445489.1, AL390774.2, AL390774.1, PIGFP2, LHX2, AC006450.3, AC006450.1, AC006450.2, NEK6, AL162724.2, AL162724.1, PSMB7, ADGRD2, NR5A1, AL354979.1, NR6A1, AL669818.1, RN7SL302P, MIR181A2HG, MIR181A2, MIR181B2, AL354928.1, OLFML2A, WDR38, RPL35, ARPC5L, GOLGA1, RNU4-82P, SCAI, FXNP2, PPP6C, PRPS1P2, RPSAP76, RABEPK, HSPA5, AL354710.2.
- chr9:125,263,845–125,304,026, 2 genes, copy number 9: AL354710.1, RNU6-1020P.
- chr10:274,190–689,668, 1 gene, copy number 8 (within-gene range 2–8): DIP2C.
- chr10:430,239–9,309,772, 164 genes, copy number 8 (broad region; genes not listed).
- chr12:66,767–38,087,392, 853 genes, copy number 15–19 (broad region; genes not listed).
- chr18:47,390–12,991,173, 296 genes, copy number 7–9 (broad region; genes not listed).
- chr19:32,243,965–40,576,464, 401 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 431. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
